Somatic mutation profile of tumor specimen 0DGMHN from CCDI case PBBTLY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 4.9 years (1,807 days).
Specimen 0DGMHN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f12a630-5568-41a0-9c95-c5c903d0da63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGMI2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26741e9d-1ed1-49eb-91e0-69821581b1a7

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'UTR 3, Silent 2, Splice Site 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUS2 | c.107C>G p.A36G | Missense Mutation (SNP) | VAF 114/706 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100732642; called by muse, mutect2, varscan2
- HS3ST3A1 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 240/1730 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs752613971, COSV52372979; called by muse, mutect2, varscan2
- MMP27 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 40/810 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs779608210; called by muse, mutect2
- OR5A2 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 32/950 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs953175005; called by muse, mutect2
- ANXA7 | c.1173G>C p.L391F (on ENST00000372919 / NM_001320880.2; = p.L369F on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/1432 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2
- CSMD1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 36/1450 reads (2%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- KBTBD4 | c.884_889dup p.P295_R296dup | In Frame Ins (INS) | VAF 292/363 reads (80%) | called by mutect2, varscan2
- PPP2R2A | c.7+1G>T p.X3_splice | Splice Site (SNP) | VAF 37/669 reads (6%) | called by muse, mutect2
- TCTN2 | c.1039G>C p.V347L | Missense Mutation (SNP) | VAF 170/710 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- ZBTB17 | c.31T>G p.L11V | Missense Mutation (SNP) | VAF 41/1212 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZNF792 | c.1792T>C p.S598P | Missense Mutation (SNP) | VAF 22/897 reads (2%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2
- APOA4 | c.180C>G p.A60= | Silent (SNP) | VAF 78/1008 reads (8%) | called by muse, mutect2
- HDAC5 | c.579G>A p.S193= | Silent (SNP) | VAF 35/756 reads (5%) | catalogued as rs1481818318; called by muse, mutect2
- GALNS | c.*99C>A | 3'UTR (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- SDHAF4 | c.*51T>C | 3'UTR (SNP) | VAF 81/329 reads (25%) | called by muse, mutect2, varscan2
- SYDE1 | c.*41C>T | 3'UTR (SNP) | VAF 89/288 reads (31%) | catalogued as rs540177418, COSV54618539; called by muse, mutect2, varscan2
